Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5710, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5710-01A (Primary Tumor).

PATIENT HISTORY:

No clinical history is given.

PRE-OP DIAGNOSIS: Right renal mass.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Right nephrectomy.

FINAL DIAGNOSIS:**KIDNEY, RIGHT, NEPHRECTOMY –**

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE WITH MYXOID CHANGES AND NECROSIS.
- B. FUHRMAN NUCLEAR GRADE IS II OF IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 5.7 cm.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY SHOWS CHANGES DUE TO PROXIMITY THE TUMOR.
- I. TNM STAGE: pT1b NX MX.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY KIDNEY TUMORS**

SPECIMEN TYPE: Other: Nephrectomy

LATERALITY: Right

TUMOR SITE: Lower pole

FOCALITY: Unifocal

TUMOR SIZE: Greatest dimension: 5.7 cm

Additional dimensions: 4.4 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney

HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma

HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G2

PATHOLOGIC STAGING (pTNM): pT1b

pNX

Number of regional lymph nodes examined: 0

pMX

MARGINS: Margins uninvolved by invasive carcinoma

ADRENAL GLAND: Not present

VENOUS (LARGE VESSEL) INVASION (V): Absent

LYMPHATIC (SMALL VESSEL) INVASION (L): Absent

ADDITIONAL PATHOLOGIC FINDINGS: None identified

Source: NCI Genomic Data Commons file 85fc4bb6-3261-4165-a158-1edaf971f0fa (TCGA-B0-5710.DF52C82E-338F-469F-AAAA-545A858E7DB0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).